Surgical pathology report (de-identified scan), TCGA case TCGA-14-1794, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1794-01A (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

TCGA-14-1794

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: AP REPORT
Encounter info:

* Final Report *

AP REPORT

Patient:

Accession Number:

Patient Number:

Date Collected:

Financial Number:

Date Received:

Room/Bed:

PT:

Admitting Physician:

Ordering Physician:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. RIGHT FRONTAL BRAIN LESION, BIOPSY, FS1A:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
2. RIGHT FRONTAL BRAIN LESION, EXCISION:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
- SEE COMMENT.

(Electronic Signature)

COMMENT:

This primary glioma shows the following features for the diagnosis of glioblastoma: high cellularity, mitotic activity, vascular proliferation, and necrosis.

SPECIMEN:

1. Right frontal brain lesion.
2. Right frontal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Frontal craniotomy for brain tumor resection. Right frontal mass.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
AP Report

* Final Report *

TCGA-14-1794

GROSS DESCRIPTION:

Two specimens are received, each labeled with the patient's name and medical record number.

Specimen #1 is received fresh for intraoperative consultation, labeled "right frontal brain lesion" and consists of three pieces of soft tan tissue measuring 2.5 x 1.5 x 0.4 cm in aggregate. A touch preparation is performed. A representative section is submitted for frozen tissue diagnosis, and the contents of the cryoblock are submitted in cassette "FS1A." The remainder of the specimen is submitted in cassette "1B."

Specimen #2 is received in formalin, labeled "right frontal brain lesion" and consists of multiple pieces of hemorrhagic tan tissue measuring 9.0 x 3.7 x 0.7 cm in aggregate. Representative sections are submitted in cassettes "2A" and "2B."

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: RIGHT FRONTAL BRAIN LESION, BIOPSY (FROZEN SECTION, TOUCH PREPARATION): GLIOBLASTOMA MULTIFORME.

Pathologist:

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Medical Records

Page 1 (End of Report)

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 31b28075-a0d3-419c-9eb1-a4250c8f1c97 (TCGA-14-1794.B71B1650-B066-4179-9C2B-D0412ACB7B77.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).